CPTAC case 03BR013 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/771110e5-c366-4ace-bdd3-a3453e01f6a7

Demographics
Sex at birth: female.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.0 years (19,010 days); AJCC pathologic stage: Stage IIA; Prior malignancy: no.

Biospecimens (3 samples)
- Samples 01f203fd-e664-4d78-bea0-7c40cf, d0dd0347-9b0f-46fe-8d62-bf17f3 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 24c38c22-1518-40bf-9f39-043d7d: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
